Gene-level copy-number profile of tumor specimen TCGA-2Z-A9JG-01A from TCGA case TCGA-2Z-A9JG, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.2 years (23,458 days).
Specimen TCGA-2Z-A9JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.bd89cd03-e38d-4745-8409-1f477f60e1f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9JG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00b51d59-02a7-46db-a13d-a968b89357ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,551; copy number 2: 27,473; copy number 3: 25,206; copy number 4: 650; copy number 5: 3,854; copy number 6: 77; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9JG-01A-11D-A42I-01): tumor purity 0.85, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,935 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,167,159–10,295,579, 9 genes, copy number 6: AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene, copy number 6: AC008638.3.
- chr12:10,824,960–11,171,608, 1 gene, copy number 5 (within-gene range 4–5): PRH1.
- chr12:10,845,849–11,171,600, 1 gene, copy number 5 (within-gene range 4–5): AC018630.4.
- chr12:10,937,408–11,171,573, 1 gene, copy number 5 (within-gene range 4–5): TAS2R14.
- chr12:10,996,495–127,636,488, 2,464 genes, copy number 5–9 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
